Somatic mutation profile of tumor specimen MMRF_1855_1_BM_CD138pos (aliquot MMRF_1855_1_BM_CD138pos_T1_KBS5U_L05777) from MMRF case MMRF_1855, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.5 years (22,841 days).
Specimen MMRF_1855_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0d2a644-d1a1-44ce-a30b-29abc9e87f76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1855_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1855_1_PB_Whole_C3_KBS5U_L05803; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28291e95-26ba-47b9-be12-ed60e15b03fb

The open-access MAF lists 465 somatic variants for this specimen: 154 protein-altering or splice-affecting, 69 silent, 242 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, 3'UTR 108, Intron 70, Silent 69, 5'UTR 36, 5'Flank 13, Nonsense Mutation 10, 3'Flank 8, RNA 7, Splice Region 3, Frame Shift Del 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC12A5 | c.641C>T p.A214V (on ENST00000454036 / NM_001134771.2; = p.A191V on NM_020708.5) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568859798; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM19 | c.2117G>A p.G706E | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.795); catalogued as COSV57431242, COSV99976463; called by muse, mutect2, varscan2
- AGAP2 | c.2091G>C p.K697N (on ENST00000547588 / NM_001122772.2; = p.K361N on NM_014770.4) | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57731582; called by muse, mutect2, varscan2
- ARHGEF26 | c.1818C>A p.C606* | Nonsense Mutation (SNP) | VAF 60/141 reads (43%) | catalogued as rs756492851; called by muse, mutect2, varscan2
- CALCR | c.1120G>A p.V374I (on ENST00000649521 / NM_001164737.2; = p.V358I on NM_001742.4) | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs375960623; called by muse, mutect2, varscan2
- CFAP54 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1458899874; called by muse, mutect2, varscan2
- COL6A3 | c.4064C>T p.P1355L | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs140863092, COSV99801569; called by muse, mutect2, varscan2
- CPED1 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201993865, COSV60002594; called by muse, mutect2, varscan2
- DNAH17 | c.10820C>T p.S3607L | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as rs144312078; called by muse, mutect2, varscan2
- EPHX2 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs770615757, COSV66844337; called by muse, mutect2, varscan2
- EYA1 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58159368; called by muse, mutect2, varscan2
- FAR1 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100701531; called by mutect2, varscan2
- FRY | c.7783G>A p.E2595K | Missense Mutation (SNP) | VAF 42/42 reads (100%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.017); catalogued as rs764241371; called by muse, mutect2, varscan2
- HARS1 | c.93C>T p.I31= | Splice Region (SNP) | VAF 14/25 reads (56%) | catalogued as COSV100047553; called by muse, mutect2, varscan2
- HELZ2 | c.4097G>A p.C1366Y (on ENST00000467148 / NM_001037335.2; = p.C797Y on NM_033405.3) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71295742; called by muse, mutect2
- HPSE | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs547265187, COSV60986997; called by muse, mutect2, varscan2
- HSD17B4 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1018612914; called by muse, mutect2, varscan2
- IGKV4-1 | c.25A>T p.I9F | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT tolerated (0.7); PolyPhen benign (0.083); catalogued as rs760823824; called by muse, varscan2
- IGLV3-1 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 42/43 reads (98%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs548457166; called by muse, varscan2
- IGLV3-1 | c.299A>T p.D100V | Missense Mutation (SNP) | VAF 44/45 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527556136; called by muse, varscan2
- ISYNA1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370519381; called by muse, mutect2, varscan2
- LRIG1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV56236283; called by muse, mutect2, varscan2
- LRRC58 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.89); PolyPhen benign (0.01); catalogued as rs1436698761; called by muse, mutect2, varscan2
- LRRD1 | c.799A>G p.N267D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563192793; called by muse, mutect2, varscan2
- MCCC2 | c.230C>G p.S77* | Nonsense Mutation (SNP) | VAF 76/135 reads (56%) | catalogued as rs1304896406; called by muse, mutect2, varscan2
- MCL1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 86/315 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100329685; called by muse, mutect2, varscan2
- MKX | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV65391461, COSV65391744; called by muse, mutect2, varscan2
- MLLT10 | c.656C>G p.S219C | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs761719782, COSV57005489; called by muse, mutect2, varscan2
- MPEG1 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); catalogued as COSV57091371; called by muse, mutect2, varscan2
- MYO1D | c.2384C>T p.S795L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs1192098799; called by muse, mutect2, varscan2
- MYO1F | c.3196G>T p.E1066* | Nonsense Mutation (SNP) | VAF 59/118 reads (50%) | catalogued as COSV57791838; called by muse, mutect2, varscan2
- NDUFB7 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV53108084; called by muse, mutect2, varscan2
- OR2J3 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs983022123; called by muse, mutect2, varscan2
- PCDHGA4 | c.2199del p.C733Wfs*11 | Frame Shift Del (DEL) | VAF 58/114 reads (51%) | catalogued as COSV53899379; called by mutect2, varscan2
- PEX5L | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 82/84 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs991897183, COSV99830243; called by muse, mutect2, varscan2
- PIEZO2 | c.6451G>C p.E2151Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.389); catalogued as COSV53295303; called by muse, mutect2, varscan2
- PKLR | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.93); catalogued as COSV100712826; called by muse, mutect2, varscan2
- PLEC | c.1546G>A p.E516K (on ENST00000322810 / NM_201380.4; = p.E406K on NM_000445.5) | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs782428063; called by muse, mutect2
- PLEKHB1 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as rs779693667; called by muse, mutect2, varscan2
- PMPCB | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs34011085; called by muse, mutect2, varscan2
- PPP1R9B | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.14); catalogued as rs1313018146, COSV57541690; called by muse, mutect2, varscan2
- PPT1 | c.853G>A p.E285K (on ENST00000433473; = p.E286K on NM_000310.4) | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs141405110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRDM12 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV53391824; called by muse, mutect2, varscan2
- SEMA3D | c.555C>G p.F185L | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as COSV52390584, COSV52397941; called by muse, mutect2, varscan2
- SLC9A7 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 87/89 reads (98%) | SIFT tolerated (0.81); PolyPhen benign (0.104); catalogued as COSV100092624; called by muse, mutect2, varscan2
- SP140 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV100613889; called by muse, mutect2, varscan2
- SPTA1 | c.6404C>G p.S2135C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV100935636; called by muse, mutect2, varscan2
- SPTBN1 | c.1578G>A p.M526I | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV61689673; called by muse, mutect2, varscan2
- STAP2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV101654909, COSV74075441; called by muse, mutect2, varscan2
- TAF15 | c.1162C>T p.R388C (on ENST00000605844 / NM_139215.3; = p.R385C on NM_003487.4) | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as rs202180032; called by muse, mutect2, varscan2
- TDRD1 | c.385-1G>A p.X129_splice | Splice Site (SNP) | VAF 45/95 reads (47%) | catalogued as rs746542884, COSV99314092; called by muse, mutect2, varscan2
- TIGD5 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1211583093, COSV57817610; called by muse, mutect2, varscan2
- TJP3 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99516368; called by muse, mutect2, varscan2
- TMC2 | c.2444C>G p.S815* | Nonsense Mutation (SNP) | VAF 80/159 reads (50%) | catalogued as COSV62656942; called by muse, mutect2, varscan2
- TMEM229A | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs904195407; called by muse, mutect2, varscan2
- TTN | c.31006G>A p.E10336K (on ENST00000591111; = p.E9409K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | PolyPhen benign (0.015); catalogued as rs1340448389; called by muse, mutect2, varscan2
- ZNF536 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 84/168 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62817809; called by muse, varscan2
- ZNF610 | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1479125702; called by muse, mutect2, varscan2
- ZNF622 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58074636; called by muse, mutect2, varscan2
- ADARB2 | c.1242G>T p.K414N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDH16A1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 85/171 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- ALG10 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AMOTL1 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 111/114 reads (97%) | SIFT deleterious (0.02); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- ANKRD31 | c.4205G>A p.R1402K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ARHGAP44 | c.75G>C p.L25F | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF7 | c.2197+1G>A p.X733_splice (on ENST00000375741 / NM_001113511.2; = p.X555_splice on NM_003899.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- ATP11C | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 23/23 reads (100%) | called by muse, mutect2, varscan2
- BAG6 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- BFSP2 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- BMP3 | c.998A>C p.K333T | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- BRMS1L | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- C5 | c.2906C>A p.P969H | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CARMIL1 | c.800C>G p.A267G | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- CCDC93 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CDKN2AIP | c.443del p.G148Efs*32 | Frame Shift Del (DEL) | VAF 40/249 reads (16%) | called by mutect2, pindel, varscan2
- CIT | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CWC25 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CYP3A4 | c.1443G>A p.M481I (on ENST00000336411; = p.M450I on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH12 | c.3773G>A p.G1258E (on ENST00000351747; = p.G1281E on NM_001366028.2) | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF5B | c.3001T>G p.S1001A | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); called by muse, varscan2
- ELP4 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ERMP1 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ESRRB | c.1398G>C p.Q466H | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- F5 | c.4498G>C p.D1500H | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- FAM13A | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM160A1 | c.3037T>C p.F1013L | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FAM20C | c.32T>A p.V11E | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- FAT4 | c.7444C>G p.L2482V | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- FN1 | c.7015G>A p.E2339K (on ENST00000359671 / NM_001365524.2; = p.E2308K on NM_002026.4) | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- GMIP | c.1255C>G p.P419A | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.76); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRIK1 | c.2022G>C p.L674F | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM2 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 64/108 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- H1-5 | c.185_191del p.L62Sfs*6 | Frame Shift Del (DEL) | VAF 58/112 reads (52%) | called by mutect2, pindel, varscan2
- HK3 | c.2381C>G p.S794C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLTF | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- HMMR | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- HUWE1 | c.3621G>T p.E1207D | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- IGHV3-33 | c.297T>A p.Y99* | Nonsense Mutation (SNP) | VAF 62/177 reads (35%) | called by muse, mutect2, varscan2
- IGKV4-1 | c.48T>A p.S16= | Splice Region (SNP) | VAF 28/28 reads (100%) | called by muse, varscan2
- IK | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IQCB1 | c.648C>G p.F216L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ITGA8 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- JCAD | c.3972C>G p.S1324R | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- KIF14 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- KMT2D | c.13141G>C p.D4381H | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- LRBA | c.3710C>G p.S1237C | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- LRP1B | c.1178A>C p.Y393S | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRP4 | c.4463C>T p.T1488I | Missense Mutation (SNP) | VAF 93/188 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- LRRC25 | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- LTK | c.2563C>T p.Q855* | Nonsense Mutation (SNP) | VAF 37/61 reads (61%) | called by muse, mutect2, varscan2
- MAST4 | c.3104T>G p.F1035C (on ENST00000403625 / NM_001164664.2; = p.F846C on NM_015183.3) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- MYO10 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- NDUFAF2 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NIPA2 | c.1028A>G p.E343G | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- NME9 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 79/160 reads (49%) | called by muse, mutect2, varscan2
- P4HA3 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PCDHGB6 | c.2357G>C p.G786A | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PIK3R5 | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PLEC | c.3442C>A p.L1148M (on ENST00000322810 / NM_201380.4; = p.L1038M on NM_000445.5) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PRDM14 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PSMD4 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 85/112 reads (76%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSME4 | c.3517C>G p.L1173V | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PURA | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 104/207 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- RAB11FIP5 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAG2 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- RASSF10 | c.1238C>G p.S413W | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- RERG | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- RPL5 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RYR1 | c.9054G>C p.L3018F | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SBNO1 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEC22C | c.905_*16del | Nonstop Mutation (DEL) | VAF 18/46 reads (39%) | called by mutect2, varscan2
- SFSWAP | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SHISA7 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SLC12A7 | c.2783T>C p.M928T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SLC26A4 | c.-3-5C>T | Splice Region (SNP) | VAF 35/61 reads (57%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.1397C>G p.S466C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- SMYD1 | c.696G>A p.M232I | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- SOX4 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- STT3B | c.1754G>C p.R585T | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYN2 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TAOK3 | c.2671G>C p.D891H | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- TDRD10 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- TMF1 | c.2948C>T p.S983L | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TPGS2 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TRIM3 | c.2126C>T p.S709F | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- TTN | c.83113G>A p.D27705N (on ENST00000591111; = p.D20281N on NM_003319.4) | Missense Mutation (SNP) | VAF 97/178 reads (54%) | PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- UBXN7 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- UFL1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 71/131 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- UGT2B4 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- VWA5A | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XBP1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 26/26 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ZNF248 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); called by muse, mutect2
- ZNF516 | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ZNF727 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ABCB6 | c.87C>T p.F29= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as CD128906; called by muse, mutect2, varscan2
- ACTRT3 | c.456G>A p.L152= | Silent (SNP) | VAF 169/235 reads (72%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.2307G>T p.G769= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as rs763979086; called by muse, mutect2, varscan2
- AGPAT2 | c.396C>T p.I132= | Silent (SNP) | VAF 72/142 reads (51%) | called by muse, mutect2, varscan2
- AOC3 | c.1032C>T p.F344= | Silent (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- ATMIN | c.204G>A p.L68= | Silent (SNP) | VAF 11/11 reads (100%) | called by muse, mutect2, varscan2
- ATP6V1F | c.51G>A p.V17= | Silent (SNP) | VAF 53/108 reads (49%) | called by muse, mutect2, varscan2
- BCKDHB | c.108G>A p.L36= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs1335346723; called by muse, mutect2, varscan2
- CATSPERG | c.2244C>G p.L748= | Silent (SNP) | VAF 75/164 reads (46%) | called by muse, mutect2, varscan2
- CCDC183 | c.990G>A p.E330= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV61035177; called by muse, mutect2, varscan2
- CFAP251 | c.669C>T p.I223= | Silent (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.1932C>T p.V644= | Silent (SNP) | VAF 65/66 reads (98%) | catalogued as rs766597788; called by muse, mutect2, varscan2
- COL4A6 | c.4386G>A p.Q1462= | Silent (SNP) | VAF 53/53 reads (100%) | called by muse, mutect2, varscan2
- COL6A6 | c.1467G>A p.E489= | Silent (SNP) | VAF 58/108 reads (54%) | catalogued as rs1289811677; called by muse, mutect2, varscan2
- COL9A2 | c.1866C>T p.I622= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs770970103, COSV101028639; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL9A3 | c.924G>A p.Q308= | Silent (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- DHX33 | c.801G>A p.Q267= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV56578144; called by muse, mutect2, varscan2
- DOCK2 | c.2289G>A p.Q763= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- DPM2 | c.57C>T p.I19= | Silent (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- FAM162A | c.19C>T p.L7= | Silent (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- FLOT1 | c.228G>A p.Q76= | Silent (SNP) | VAF 44/75 reads (59%) | called by muse, mutect2, varscan2
- FOLH1 | c.105C>T p.L35= | Silent (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- FRZB | c.75C>A p.L25= | Silent (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- GRK1 | c.1389G>A p.L463= | Silent (SNP) | VAF 15/16 reads (94%) | called by muse, mutect2, varscan2
- GRM8 | c.42C>T p.F14= | Silent (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- HYAL4 | c.906C>G p.V302= | Silent (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- IRAG1 | c.2676G>A p.S892= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs373757978; called by muse, mutect2, varscan2
- KCNQ2 | c.1869C>G p.L623= (on ENST00000359125 / NM_172107.4; = p.L595= on NM_004518.6) | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV60549218; called by muse, mutect2, varscan2
- KDM1A | c.315G>T p.P105= | Silent (SNP) | VAF 49/79 reads (62%) | called by muse, mutect2, varscan2
- LRTM1 | c.903C>T p.L301= | Silent (SNP) | VAF 52/114 reads (46%) | called by muse, mutect2, varscan2
- MARVELD2 | c.1272G>A p.L424= | Silent (SNP) | VAF 59/99 reads (60%) | catalogued as rs1487718754; called by muse, mutect2, varscan2
- MBLAC2 | c.12C>T p.L4= | Silent (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- MCIDAS | c.759C>A p.A253= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2
- MCOLN1 | c.891C>T p.F297= | Silent (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- MDC1 | c.2166C>T p.F722= | Silent (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- MLH1 | c.1189C>T p.L397= | Silent (SNP) | VAF 59/117 reads (50%) | catalogued as COSV51625855; called by muse, mutect2, varscan2
- MLLT3 | c.351C>G p.L117= | Silent (SNP) | VAF 35/91 reads (38%) | called by muse, mutect2, varscan2
- MOV10 | c.108G>A p.R36= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as COSV54146826; called by muse, mutect2, varscan2
- NELFA | c.534G>A p.R178= (on ENST00000542778; = p.R167= on NM_005663.5) | Silent (SNP) | VAF 52/117 reads (44%) | called by muse, mutect2, varscan2
- NPHS1 | c.255G>A p.L85= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as rs1192855645, COSV100800213; called by muse, mutect2, varscan2
- NRAP | c.4368C>T p.F1456= (on ENST00000359988 / NM_001322945.2; = p.F1421= on NM_006175.4) | Silent (SNP) | VAF 56/109 reads (51%) | catalogued as COSV63491629; called by muse, mutect2, varscan2
- OR5K3 | c.912G>A p.K304= | Silent (SNP) | VAF 92/184 reads (50%) | catalogued as rs935073343; called by muse, mutect2, varscan2
- PALLD | c.987G>T p.L329= | Silent (SNP) | VAF 49/104 reads (47%) | catalogued as rs1254027436; called by muse, mutect2, varscan2
- PCBP1 | c.228C>T p.I76= | Silent (SNP) | VAF 55/111 reads (50%) | catalogued as rs772335235; called by muse, mutect2, varscan2
- PCNT | c.189C>T p.L63= | Silent (SNP) | VAF 50/95 reads (53%) | catalogued as COSV52450898; called by muse, mutect2, varscan2
- PLA2G10 | c.465C>T p.F155= | Silent (SNP) | VAF 99/198 reads (50%) | called by muse, mutect2, varscan2
- PLA2G2C | c.18C>A p.I6= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- POM121 | c.378C>T p.L126= | Silent (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- PPP1R16A | c.1586G>A p.*529= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs1484556151; called by muse, mutect2, varscan2
- RANBP2 | c.4794A>C p.G1598= | Silent (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- RANGAP1 | c.1521C>T p.F507= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- RAPH1 | c.2103C>T p.I701= | Silent (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- RBM15 | c.2377C>T p.L793= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs766032995; called by muse, mutect2, varscan2
- RBM15B | c.2409G>T p.G803= | Silent (SNP) | VAF 64/114 reads (56%) | catalogued as COSV60041404; called by muse, varscan2
- RRM2B | c.189C>T p.F63= | Silent (SNP) | VAF 81/172 reads (47%) | called by muse, mutect2, varscan2
- SCLY | c.537G>A p.V179= (on ENST00000651534; = p.V171= on NM_016510.7) | Silent (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- SCN1A | c.2196G>A p.Q732= (on ENST00000303395 / NM_001202435.3; = p.Q721= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- SPECC1 | c.2055C>T p.L685= | Silent (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- SPPL2C | c.1506C>G p.L502= | Silent (SNP) | VAF 61/150 reads (41%) | called by muse, mutect2, varscan2
- SUSD4 | c.978G>A p.T326= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as rs780896543; called by muse, mutect2, varscan2
- TMEM131 | c.2502G>C p.R834= | Silent (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- TRIM49B | c.123C>A p.L41= | Silent (SNP) | VAF 45/93 reads (48%) | called by muse, mutect2, varscan2
- TTLL7 | c.2571C>T p.F857= | Silent (SNP) | VAF 42/113 reads (37%) | called by muse, mutect2, varscan2
- TWIST1 | c.294G>T p.G98= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV54251118; called by muse, mutect2, varscan2
- VWA1 | c.636G>A p.A212= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs781470522, COSV58599802; called by muse, mutect2, varscan2
- WDR74 | c.279C>T p.L93= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs377645483; called by muse, mutect2, varscan2
- ZNF551 | c.1212C>T p.F404= | Silent (SNP) | VAF 60/117 reads (51%) | called by muse, mutect2, varscan2
- ZNF628 | c.2622C>G p.L874= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV52699446; called by muse, mutect2, varscan2
- ZNF703 | c.360G>A p.L120= | Silent (SNP) | VAF 24/39 reads (62%) | catalogued as rs1373900174; called by muse, mutect2, varscan2
- ABCG2 | chr4:88159207 C>T | 5'Flank (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2, varscan2
- AC005726.1 | c.524+13698C>A | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- AC015910.1 | n.361G>C | RNA (SNP) | VAF 47/101 reads (47%) | called by muse, mutect2, varscan2
- AC084082.1 | n.211G>A | RNA (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- AC092587.1 | c.-27-5007G>A | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- ACYP2 | c.185+3347G>T | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- ADAM22 | chr7:88199924 C>T | 3'Flank (SNP) | VAF 54/101 reads (53%) | called by muse, mutect2, varscan2
- ADD2 | c.*3245G>C | 3'UTR (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- ADD2 | c.1593+878G>A | Intron (SNP) | VAF 18/59 reads (31%) | catalogued as COSV52456242; called by muse, mutect2, varscan2
- ADGRA1 | chr10:133085036 G>T | 5'Flank (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827666 A>G | 3'Flank (SNP) | VAF 38/38 reads (100%) | called by muse, mutect2, varscan2
- AMACR | c.*2274C>T | 3'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- AMZ1 | c.*1894C>T | 3'UTR (SNP) | VAF 42/91 reads (46%) | called by muse, mutect2, varscan2
- ANK2 | c.85-28638G>T | Intron (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498508 C>G | 5'Flank (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- AP001267.5 | c.-799+32919C>T | Intron (SNP) | VAF 102/102 reads (100%) | called by muse, mutect2, varscan2
- APBB2 | c.1104+14C>A | Intron (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- APH1A | c.358+60C>T | Intron (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- AR | c.*730G>A | 3'UTR (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
- ARG1 | c.57+837C>T | Intron (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- ARHGEF6 | c.*2267G>A | 3'UTR (SNP) | VAF 31/31 reads (100%) | called by muse, mutect2, varscan2
- ASAH1 | c.126+98G>A | Intron (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- ATG14 | c.*1425C>T | 3'UTR (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- AVIL | c.2152-78G>A | Intron (SNP) | VAF 55/99 reads (56%) | catalogued as rs1033480074; called by muse, mutect2, varscan2
- B3GNT6 | c.*263C>T | 3'UTR (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021487 T>C | 5'Flank (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2, varscan2
- BMP7 | c.*10G>C | 3'UTR (SNP) | VAF 23/47 reads (49%) | catalogued as COSV101216110; called by muse, mutect2, varscan2
- BORCS5 | c.*634C>T | 3'UTR (SNP) | VAF 55/130 reads (42%) | called by muse, mutect2, varscan2
- BTG1 | c.*769C>G | 3'UTR (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+4127C>G | Intron (SNP) | VAF 58/129 reads (45%) | called by muse, mutect2
- C12orf42 | n.398+3312G>A | Intron (SNP) | VAF 42/73 reads (58%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.-14-39C>G | Intron (SNP) | VAF 64/130 reads (49%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.2974+12G>A | Intron (SNP) | VAF 89/191 reads (47%) | catalogued as rs71454841, COSV54960680; called by muse, mutect2, varscan2
- CACNB1 | c.*473C>T | 3'UTR (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- CALML3-AS1 | n.2843C>T | RNA (SNP) | VAF 37/78 reads (47%) | catalogued as rs934008065; called by muse, mutect2, varscan2
- CAND1 | c.*3389G>A | 3'UTR (SNP) | VAF 50/91 reads (55%) | called by muse, mutect2
- CCDC174 | c.*788C>T | 3'UTR (SNP) | VAF 22/53 reads (42%) | catalogued as rs1474576428; called by muse, mutect2, varscan2
- CCDC93 | c.364-95G>A | Intron (SNP) | VAF 18/43 reads (42%) | called by mutect2, varscan2
- CCNY | c.*197C>G | 3'UTR (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- CD37 | c.*96G>A | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- CHRM3 | c.*4486G>A | 3'UTR (SNP) | VAF 34/133 reads (26%) | called by muse, mutect2, varscan2
- CILK1 | c.*267T>G | 3'UTR (SNP) | VAF 11/84 reads (13%) | catalogued as rs532710841; called by muse, mutect2, varscan2
- CNTNAP5 | c.*738G>A | 3'UTR (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- COBLL1 | c.1340-423C>A | Intron (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- CORO1A | chr16:30183100 C>T | 5'Flank (SNP) | VAF 37/62 reads (60%) | called by muse, mutect2, varscan2
- CPEB4 | c.-1234C>T | 5'UTR (SNP) | VAF 17/51 reads (33%) | catalogued as rs770953250; called by muse, mutect2, varscan2
- CPS1 | c.*1012A>T | 3'UTR (SNP) | VAF 36/66 reads (55%) | called by muse, mutect2, varscan2
- CREB1 | c.*3088C>G | 3'UTR (SNP) | VAF 22/43 reads (51%) | catalogued as rs975349026; called by muse, mutect2, varscan2
- CRY1 | c.-292G>A | 5'UTR (SNP) | VAF 73/120 reads (61%) | called by muse, mutect2, varscan2
- CSTL1 | chr20:23440222 C>A | 5'Flank (SNP) | VAF 17/101 reads (17%) | catalogued as rs1235649607; called by muse, mutect2, varscan2
- CTDSP1 | chr2:218398440 G>A | 5'Flank (SNP) | VAF 58/118 reads (49%) | called by muse, mutect2, varscan2
- CYTH2 | c.-90G>A | 5'UTR (SNP) | VAF 12/16 reads (75%) | called by muse, mutect2, varscan2
- DCC | c.*1213C>A | 3'UTR (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- DCLK3 | c.*1382C>T | 3'UTR (SNP) | VAF 38/90 reads (42%) | called by muse, mutect2, varscan2
- DGKB | c.*3889C>T | 3'UTR (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- DNAJB5 | c.-35+432C>T | Intron (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- DNASE1L1 | chrX:154401469 C>G | 3'Flank (SNP) | VAF 45/46 reads (98%) | catalogued as rs911162086; called by muse, mutect2, varscan2
- DPAGT1 | chr11:119101883 C>T | 5'Flank (SNP) | VAF 40/42 reads (95%) | called by muse, mutect2, varscan2
- DPF1 | c.677-32G>T | Intron (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- DST | c.16635+472C>G | Intron (SNP) | VAF 68/156 reads (44%) | called by muse, mutect2, varscan2
- DST | c.1146-301C>T | Intron (SNP) | VAF 27/53 reads (51%) | catalogued as rs746615493; called by muse, mutect2, varscan2
- DYNLL1P1 | n.228C>A | RNA (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- EAF2 | c.736+210C>T | Intron (SNP) | VAF 50/111 reads (45%) | called by muse, mutect2, varscan2
- EIF4E2 | c.20+102C>T | Intron (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- ENY2 | c.-11C>T | 5'UTR (SNP) | VAF 45/76 reads (59%) | catalogued as COSV53459832; called by muse, mutect2, varscan2
- EPB41L3 | c.*163G>A | 3'UTR (SNP) | VAF 49/93 reads (53%) | called by muse, mutect2, varscan2
- EPG5 | c.*2863C>G | 3'UTR (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- ERBB3 | c.*1380C>G | 3'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- ESRRG | c.*1169C>A | 3'UTR (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- ETF1 | c.86+51C>G | Intron (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- FAIM2 | c.*2066G>C | 3'UTR (SNP) | VAF 47/98 reads (48%) | called by muse, mutect2, varscan2
- FAR1 | c.*357G>A | 3'UTR (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- FCHSD2 | c.1705+97C>T | Intron (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- FGD2 | c.824-84C>T | Intron (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- FMO3 | c.*245G>C | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- FOXP2 | c.*485del | 3'UTR (DEL) | VAF 32/58 reads (55%) | called by mutect2, varscan2
- FTO | c.*4392T>G | 3'UTR (SNP) | VAF 30/30 reads (100%) | called by muse, mutect2, varscan2
- GAB2 | c.1208-21G>A | Intron (SNP) | VAF 48/93 reads (52%) | called by muse, mutect2, varscan2
- GAK | c.3284-19C>T | Intron (SNP) | VAF 22/37 reads (59%) | called by muse, mutect2, varscan2
- GALNT12 | c.*974G>C | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- GALNT2 | n.35C>T | RNA (SNP) | VAF 36/120 reads (30%) | called by muse, mutect2, varscan2
- GFM1 | c.1083+1322G>A | Intron (SNP) | VAF 10/130 reads (8%) | catalogued as COSV51831001; called by muse, mutect2
- GGA2 | c.*773del | 3'UTR (DEL) | VAF 48/98 reads (49%) | called by mutect2, pindel, varscan2
- GNS | c.*759G>A | 3'UTR (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- GPNMB | c.*71C>T | 3'UTR (SNP) | VAF 93/176 reads (53%) | catalogued as COSV99326838; called by muse, mutect2, varscan2
- GPNMB | c.*832A>G | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- GRB2 | c.*1097C>T | 3'UTR (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- GREB1 | c.1160-57A>G | Intron (SNP) | VAF 69/167 reads (41%) | catalogued as rs1225303992; called by muse, mutect2, varscan2
- GULP1 | c.843+2411G>T | Intron (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- H3C12 | c.-19G>A | 5'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- HCFC1 | c.*1659C>T | 3'UTR (SNP) | VAF 35/35 reads (100%) | catalogued as rs782425910; called by muse, mutect2, varscan2
- HDAC6 | chrX:48801995 G>T | 5'Flank (SNP) | VAF 16/16 reads (100%) | called by muse, mutect2, varscan2
- HEXD | c.*47C>G | 3'UTR (SNP) | VAF 26/46 reads (57%) | called by muse, mutect2, varscan2
- HNRNPC | chr14:21209328 G>A | 3'Flank (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.-985C>T | 5'UTR (SNP) | VAF 63/130 reads (48%) | called by muse, mutect2, varscan2
- HNRNPUL1 | c.786+43C>A | Intron (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- HORMAD1 | c.*523dup | 3'UTR (INS) | VAF 24/86 reads (28%) | catalogued as rs896602929; called by mutect2, varscan2
- HS2ST1 | c.-260C>T | 5'UTR (SNP) | VAF 12/28 reads (43%) | catalogued as rs943402482; called by muse, mutect2, varscan2
- HSBP1 | c.-32G>A | 5'UTR (SNP) | VAF 21/21 reads (100%) | called by muse, mutect2, varscan2
- ICE2 | c.*3968G>C | 3'UTR (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- IFIT2 | c.*1460G>A | 3'UTR (SNP) | VAF 19/41 reads (46%) | catalogued as rs1157187415; called by muse, mutect2, varscan2
- IGKV4-1 | c.-112T>C | 5'UTR (SNP) | VAF 10/10 reads (100%) | called by muse, varscan2
- IGKV4-1 | c.-102T>C | 5'UTR (SNP) | VAF 10/10 reads (100%) | called by muse, varscan2
- IHO1 | chr3:49258048 G>C | 3'Flank (SNP) | VAF 16/39 reads (41%) | catalogued as rs534630414; called by muse, mutect2, varscan2
- IKBKE | c.1835+253G>T | Intron (SNP) | VAF 62/96 reads (65%) | called by muse, mutect2, varscan2
- IL18RAP | c.-100-9G>A | Intron (SNP) | VAF 78/151 reads (52%) | called by muse, mutect2, varscan2
- IL2RB | c.*1428C>T | 3'UTR (SNP) | VAF 41/41 reads (100%) | called by muse, mutect2, varscan2
- IL2RB | c.*518C>G | 3'UTR (SNP) | VAF 36/36 reads (100%) | called by muse, mutect2, varscan2
- IL6ST | c.*5896C>G | 3'UTR (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- IRF1 | c.853+135C>T | Intron (SNP) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- IZUMO1 | c.418+94T>A | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- JCAD | c.*2297C>T | 3'UTR (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- JCAD | c.*9C>T | 3'UTR (SNP) | VAF 59/123 reads (48%) | catalogued as rs778939984; called by muse, mutect2, varscan2
- JUND | chr19:18282110 C>T | 5'Flank (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
- KHDC1 | c.-350C>T | 5'UTR (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
- KIFC1 | c.-92C>T | 5'UTR (SNP) | VAF 50/87 reads (57%) | catalogued as COSV68970033; called by muse, mutect2, varscan2
- LEPROT | c.*362C>T | 3'UTR (SNP) | VAF 9/73 reads (12%) | catalogued as rs1193658788; called by muse, mutect2, varscan2
- LGR4 | c.*935T>C | 3'UTR (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2
- LMBRD2 | c.*1500G>A | 3'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- LNX1 | c.*92G>A | 3'UTR (SNP) | VAF 20/34 reads (59%) | called by muse, mutect2, varscan2
- LONRF2 | c.*4338G>A | 3'UTR (SNP) | VAF 53/97 reads (55%) | called by muse, mutect2, varscan2
- LRPAP1 | chr4:3532434 C>T | 5'Flank (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- LRRC23 | c.*245C>T | 3'UTR (SNP) | VAF 32/65 reads (49%) | catalogued as rs782092703; called by muse, mutect2, varscan2
- LTBP4 | c.451+1318C>T | Intron (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- MBL2 | c.*2525G>A | 3'UTR (SNP) | VAF 25/60 reads (42%) | called by muse, varscan2
- MDGA2 | c.*1781T>C | 3'UTR (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- MDH1B | c.-46A>G | 5'UTR (SNP) | VAF 21/148 reads (14%) | called by muse, mutect2, varscan2
- METAP1D | c.*465C>T | 3'UTR (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- METAP1D | c.*466C>T | 3'UTR (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- MFSD4B | c.27+2610C>T | Intron (SNP) | VAF 99/204 reads (49%) | catalogued as rs1232849904; called by muse, mutect2, varscan2
- MIS18BP1 | c.*7G>A | 3'UTR (SNP) | VAF 66/137 reads (48%) | catalogued as COSV99950293; called by muse, mutect2, varscan2
- MORC3 | c.*766C>T | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- MPP5 | c.*413C>T | 3'UTR (SNP) | VAF 32/56 reads (57%) | called by muse, mutect2, varscan2
- MRAS | c.*2401G>A | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- MSR1 | c.*219C>G | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- MTX1 | chr1:155215056 G>A | 3'Flank (SNP) | VAF 33/204 reads (16%) | catalogued as rs1473797751; called by muse, mutect2, varscan2
- MYO16 | c.-39+33493G>A | Intron (SNP) | VAF 37/37 reads (100%) | catalogued as rs1183688187; called by muse, mutect2, varscan2
- NABP1 | c.*1208G>A | 3'UTR (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- NACC2 | c.*813C>T | 3'UTR (SNP) | VAF 37/61 reads (61%) | called by muse, mutect2, varscan2
- NCF2 | c.-122C>T | 5'UTR (SNP) | VAF 88/128 reads (69%) | called by muse, mutect2, varscan2
- NDUFA10 | c.*1337C>A | 3'UTR (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- NDUFB1 | c.-5-151A>G | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- NIPA2 | c.*71A>G | 3'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- NKAIN4 | c.193-31C>T | Intron (SNP) | VAF 33/59 reads (56%) | catalogued as rs377071925; called by muse, mutect2, varscan2
- NMRK1 | c.497-163C>T | Intron (SNP) | VAF 24/50 reads (48%) | catalogued as rs765634040; called by muse, mutect2
- NOL6 | c.-1G>A | 5'UTR (SNP) | VAF 86/203 reads (42%) | called by muse, mutect2, varscan2
- NRDE2 | c.*1347G>A | 3'UTR (SNP) | VAF 46/79 reads (58%) | called by muse, mutect2, varscan2
- NRK | c.-183T>A | 5'UTR (SNP) | VAF 30/121 reads (25%) | called by muse, mutect2, varscan2
- NSD2 | c.1881+489C>T | Intron (SNP) | VAF 37/70 reads (53%) | called by muse, mutect2, varscan2
- NSUN4 | c.-383G>A | 5'UTR (SNP) | VAF 89/152 reads (59%) | called by muse, mutect2, varscan2
- NUDT22 | chr11:64230021 G>C | 3'Flank (SNP) | VAF 74/145 reads (51%) | catalogued as rs1042663058; called by muse, mutect2, varscan2
- OR2AJ1 | c.-11G>A | 5'UTR (SNP) | VAF 12/54 reads (22%) | catalogued as rs149006744; called by mutect2, varscan2
- OTOG | c.2642-34C>T | Intron (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- OTUD7A | c.*243C>G | 3'UTR (SNP) | VAF 36/60 reads (60%) | called by muse, mutect2, varscan2
- PAFAH1B1 | c.671+27C>T | Intron (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- PCDHA9 | chr5:140847820 C>G | 5'Flank (SNP) | VAF 48/96 reads (50%) | called by muse, varscan2
- PDE3A | c.*1731G>A | 3'UTR (SNP) | VAF 4/62 reads (6%) | catalogued as rs1439403371; called by muse, mutect2
- PDXDC1 | c.22-8723G>C | Intron (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2
- PI4KB | c.*140C>T | 3'UTR (SNP) | VAF 108/157 reads (69%) | called by muse, mutect2, varscan2
- PMS1 | c.1856+2281G>A | Intron (SNP) | VAF 113/218 reads (52%) | called by muse, mutect2, varscan2
- PPM1G | c.*150C>G | 3'UTR (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- PPP1R12B | c.*3472G>A | 3'UTR (SNP) | VAF 85/143 reads (59%) | called by muse, mutect2, varscan2
- PPP1R1B | c.*203G>A | 3'UTR (SNP) | VAF 73/135 reads (54%) | called by muse, mutect2, varscan2
- PRDM7 | c.*488G>A | 3'UTR (SNP) | VAF 60/62 reads (97%) | called by muse, mutect2, varscan2
- PRKAG2 | c.-179C>T | 5'UTR (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- PRR4 | c.65-45G>A | Intron (SNP) | VAF 18/53 reads (34%) | catalogued as rs367790409; called by muse, mutect2, varscan2
- PTPN20 | chr10:47001092 G>A | 3'Flank (SNP) | VAF 95/219 reads (43%) | called by muse, mutect2, varscan2
- RAB11FIP1 | c.-7C>T | 5'UTR (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- RAD21 | chr8:116875983 G>C | 5'Flank (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- RAD52 | c.467+211G>C | Intron (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- RAPGEF3 | c.1923+86G>A | Intron (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99405684; called by muse, mutect2, varscan2
- RARRES2 | c.-21+395C>T | Intron (SNP) | VAF 55/97 reads (57%) | called by muse, mutect2, varscan2
- RARRES2P9 | n.457C>A | RNA (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- RBM28 | c.-25C>G | 5'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- RBM8A | c.*2109T>A | 3'UTR (SNP) | VAF 39/141 reads (28%) | called by muse, mutect2, varscan2
- RCC1 | c.-228-212_-228-210del | Intron (DEL) | VAF 34/71 reads (48%) | called by mutect2, varscan2
- RFX3 | c.*5285C>G | 3'UTR (SNP) | VAF 54/106 reads (51%) | catalogued as rs988138461; called by muse, mutect2, varscan2
- RIC8A | c.-1322G>A | 5'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- RNF181 | c.218-41G>A | Intron (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- RNF34 | c.-42G>A | 5'UTR (SNP) | VAF 16/35 reads (46%) | catalogued as rs1020005143; called by muse, mutect2, varscan2
- RNF8 | c.-77G>A | 5'UTR (SNP) | VAF 32/73 reads (44%) | catalogued as COSV57720973; called by muse, varscan2
- RPL10 | c.*25C>G | 3'UTR (SNP) | VAF 64/66 reads (97%) | called by muse, mutect2, varscan2
- RPL13A | c.256+80C>T | Intron (SNP) | VAF 108/239 reads (45%) | catalogued as rs764068196; called by muse, mutect2, varscan2
- RPS3 | c.255+63C>G | Intron (SNP) | VAF 47/108 reads (44%) | called by muse, mutect2, varscan2
- RPS6KA1 | c.613+56G>C | Intron (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- RTCB | c.-34G>A | 5'UTR (SNP) | VAF 73/78 reads (94%) | called by muse, mutect2, varscan2
- SAMSN1 | c.*524C>T | 3'UTR (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- SAPCD2 | c.*343C>T | 3'UTR (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- SENP1 | c.-123C>G | 5'UTR (SNP) | VAF 13/51 reads (25%) | catalogued as rs546578203; called by muse, mutect2, varscan2
- SERP1 | c.-237C>A | 5'UTR (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- SERPINB1 | c.*1035C>T | 3'UTR (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- SETMAR | c.156+309C>T | Intron (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- SHE | c.*4554C>T | 3'UTR (SNP) | VAF 72/91 reads (79%) | called by muse, mutect2, varscan2
- SLC11A1 | c.*928C>T | 3'UTR (SNP) | VAF 74/144 reads (51%) | called by muse, mutect2, varscan2
- SLC12A6 | c.*373C>T | 3'UTR (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- SLC13A2 | c.-12C>T | 5'UTR (SNP) | VAF 35/69 reads (51%) | catalogued as COSV100120428; called by muse, mutect2, varscan2
- SLC25A29 | c.79-101G>A | Intron (SNP) | VAF 7/14 reads (50%) | catalogued as rs964328911; called by muse, mutect2
- SLC27A6 | c.-532G>T | 5'UTR (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- SLC39A1 | c.-33+328C>T | Intron (SNP) | VAF 131/175 reads (75%) | called by muse, mutect2, varscan2
- SLC5A7 | c.*2081T>C | 3'UTR (SNP) | VAF 53/100 reads (53%) | called by muse, mutect2, varscan2
- SLC9A1 | c.*1200G>C | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- SOX5 | c.*484C>T | 3'UTR (SNP) | VAF 12/32 reads (38%) | called by muse, varscan2
- SOX9 | c.-116G>C | 5'UTR (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- SPAST | c.*2768G>A | 3'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- SSR3 | c.*2518C>G | 3'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- STAT2 | c.548-92C>T | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- SYT10 | c.-258G>C | 5'UTR (SNP) | VAF 17/33 reads (52%) | catalogued as COSV57343160; called by muse, mutect2, varscan2
- SYT8 | c.30+142G>A | Intron (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- TAAR3P | n.167G>C | RNA (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 49/92 reads (53%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TBX1 | c.1009+1164G>A | Intron (SNP) | VAF 37/37 reads (100%) | called by muse, mutect2, varscan2
- TCF4 | c.1638-79C>G | Intron (SNP) | VAF 57/106 reads (54%) | called by muse, mutect2, varscan2
- TCTN1 | c.823-189G>A | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- TDRD9 | c.*33C>T | 3'UTR (SNP) | VAF 22/48 reads (46%) | catalogued as rs933752781; called by muse, mutect2, varscan2
- TDRD9 | c.*146C>G | 3'UTR (SNP) | VAF 25/56 reads (45%) | catalogued as rs577911962; called by muse, mutect2, varscan2
- TET2 | c.-135T>C | 5'UTR (SNP) | VAF 112/225 reads (50%) | called by muse, mutect2, varscan2
- TFAP2C | c.*153G>A | 3'UTR (SNP) | VAF 65/116 reads (56%) | catalogued as rs568990583, COSV99571573; called by muse, mutect2, varscan2
- TLL2 | c.2662+56G>A | Intron (SNP) | VAF 11/30 reads (37%) | called by muse, varscan2
- TMBIM4 | c.*1208G>A | 3'UTR (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- TMEM144 | c.109+611G>C | Intron (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- TMEM201 | c.1160+167G>A | Intron (SNP) | VAF 32/75 reads (43%) | catalogued as rs985996018; called by muse, mutect2, varscan2
- TMEM263 | c.*2254C>T | 3'UTR (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2
- TMEM39A | c.*603G>T | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- TMEM41B | c.*238G>C | 3'UTR (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- TMEM72 | c.*1454_*1461del | 3'UTR (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- TNFAIP1 | c.*1535G>A | 3'UTR (SNP) | VAF 52/116 reads (45%) | called by muse, mutect2, varscan2
- TNFAIP8 | c.*539C>T | 3'UTR (SNP) | VAF 18/38 reads (47%) | called by mutect2, varscan2
- TRAPPC8 | c.-339T>C | 5'UTR (SNP) | VAF 41/84 reads (49%) | called by muse, mutect2, varscan2
- TRIM13 | c.*4616C>T | 3'UTR (SNP) | VAF 36/36 reads (100%) | called by muse, mutect2, varscan2
- TRIM3 | c.*137C>T | 3'UTR (SNP) | VAF 64/134 reads (48%) | called by muse, mutect2, varscan2
- TRIM33 | c.*885C>T | 3'UTR (SNP) | VAF 23/65 reads (35%) | catalogued as rs1247705876; called by muse, mutect2, varscan2
- USP33 | c.*870G>A | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- USP44 | c.*818G>A | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- USP47 | c.*2746G>A | 3'UTR (SNP) | VAF 35/61 reads (57%) | called by muse, mutect2, varscan2
- USP6NL | c.*307A>G | 3'UTR (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- VPS37B | c.*125G>C | 3'UTR (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2, varscan2
- WDR92 | c.*440C>T | 3'UTR (SNP) | VAF 26/53 reads (49%) | catalogued as rs1304695733; called by muse, mutect2, varscan2
- WLS | c.-19_-12del | 5'UTR (DEL) | VAF 74/146 reads (51%) | called by mutect2, varscan2
- XPO5 | c.3066+120C>A | Intron (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- YKT6 | c.561+308G>A | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- YY1AP1 | c.48-56C>G | Intron (SNP) | VAF 132/176 reads (75%) | called by muse, mutect2
- ZBTB10 | c.-439C>T | 5'UTR (SNP) | VAF 27/70 reads (39%) | called by muse, mutect2, varscan2
